Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GB-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS

A) RIGHT LEG, SKIN ELLIPSE:

Skin and soft tissue resection with healing surgical wound. See note.

Note: There is no malignant melanoma identified in these sections. Margins have been evaluated. There is also a hemangioma with arteriovenous features.

B) RIGHT SUPERFICIAL INGUINAL LYMPH NODE:

MALIGNANT MELANOMA METASTATIC TO ONE OF FIVE LYMPH NODES (1/5).

GROSS TUMOR SIZE 20.0 X 30.0 MM.

EXTRACAPSULAR EXTENSION NOT IDENTIFIED.

C) ILIAC LYMPH NODES:

Four lymph nodes negative for melanoma (0/4).

Entire report and diagnosis completed by

ICD-0-3
Melanoma NOS 8720/3
Site Inguinal lymph
node 0774
J21127/13

GROSS DESCRIPTION

(A) WIDE LOCAL EXCISION RIGHT LEG MELANOMA SITE, SHORT STITCH SUPERIOR, LONG STITCH LATERAL - An ellipse of white-tan skin (8.5 x 3.0 x 0.6 cm). The specimen orientation is short stitch superior, long stitch lateral. On the surface of the specimen a pink lesion is identified 0.6 x 0.6 cm. The lesion is located 3.5 cm from the lateral margin and 1.5 cm from the superior margin.

INK CODE: Blue - superior; yellow - inferior. The specimen is serially sectioned from medial to lateral and submitted in toto.

SECTION CODE: A1, medial tip; A2, lateral tip to include stitch; A3-A14, remainder of the specimen sequentially sectioned from medial to lateral.

(B) RIGHT SUPERFICIAL INGUINAL LYMPH NODE, STITCH MARKS HIGHEST ___ NODE - An irregular fragment of adipose tissue measuring 18.0 x 8.0 x 2.0 cm. Attached to the specimen, an irregular fragment of skin measuring 18.0 x 1.0 cm. In the surface of the specimen, there is a possible healed scar measuring 8.0 cm in length. The specimen is serially sectioned and a biopsy site is identified measuring 3.5 x 2.5 cm. In addition, 5 lymph nodes are identified ranging in size from (1.0 x 0.5 x 0.3 cm to 3.0 x 2.0 x 2.0 cm). One of the lymph nodes is marked by this stitch as the highest lymph node.

SECTION CODE: B1, representative sections of the skin; B2, 1 lymph node bisected; B3, B4, 1 lymph node serially sectioned; B5, 1 lymph node bisected; B6-B8, 1 lymph node serially sectioned; B9-B11, 1 lymph node serially sectioned-marked by the stitch as highest; B12, representative sections of the biopsy site.

(C) ILIAC LYMPH NODES - A portion of pink-tan adipose tissue (9.0 x 4.0 x 1.0 cm). The specimen is serially sectioned and four lymph nodes are identified ranging in size from 1.0 x 1.0 x 1.0 to 3.0 x 1.5 x 1.0 cm. The specimen is submitted in toto.

SECTION CODE: C1, one bisected lymph node; C2, one trisected lymph node; C3, one trisected; C4-C5, one serially sectioned lymph node.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

T-02830, M-78060, T-C4810, M-87206

[page 2 of 2]
-----END OF REPORT-----

Source: NCI Genomic Data Commons file 2859579e-e753-4dd7-ba11-eba17de05891 (TCGA-D3-A8GB.724AF606-850F-4A3F-B794-89639DDB610A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).